Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-7788, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-7788-01A (Primary Tumor).

PATIENT HISTORY:

with a history of PSA value of 26.6 ng/ml. The patient had a biopsy on prostatic adenocarcinoma Gleason score 4+3 = 7 in the right mid aspect.

PRE-OP DIAGNOSIS: Prostate cancer.

Collection Date:

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical prostatectomy with bilateral lymphadenectomy.

FINAL DIAGNOSIS:

PART 1: LYMPH NODE, RIGHT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN ONE LYMPH NODE (0/1).

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION –
NO EVIDENCE OF NEOPLASIA IN FIVE LYMPH NODES (0/5).

PART 3: PROSTATE AND BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA, RADICAL PROSTATECTOMY –

- A. PROSTATIC ADENOCARCINOMA, ACINAR TYPE, MULTIFOCAL, GLEASON SCORE 3 + 4 = 7 WITH TERTIARY GLEASON PATTERN 5, AND A TOTAL GLEASON 4/5 PERCENTAGE OF 30%.
- B. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 3.0 CM IN ONE HISTOLOGIC SECTION (SLIDE 3NN).
- C. THE CARCINOMA INVOLVES APPROXIMATELY 60% OF THE EXAMINED PROSTATE VOLUME.
- D. THE CARCINOMA SHOWS MULTIFOCAL, ESTABLISHED EXTRACAPSULAR EXTENSION IN THE REGIONS OF THE RIGHT AND LEFT SEMINAL VESICLES (SLIDES 3A & 3C), ANTERIOR RIGHT AND LEFT BASE (SLIDES 3P & 3V), POSTERIOR RIGHT AND LEFT BASE (SLIDES 3Y, 3BB, 3NN, 3QQ AND 3RR) AND POSTERIOR LEFT MID (SLIDE 3AA).
- E. THE CARCINOMA EXTENSIVELY INVOLVES THE RIGHT SEMINAL VESICLE AND FOCALLY INVOLVES THE LEFT SEMINAL VESICLE.
- F. PARTIALLY CAUTERIZED CARCINOMA EXTENSIVELY INVOLVES PROXIMAL URETHRAL/ BASILAR (SLIDES 3F & 3H) AND DISTAL URETHRAL / APICAL RESECTION MARGINS (SLIDE 3J). LINEAR EXTENT OF MARGIN POSITIVITY IS GREATER THAN 1.7 CM (SLIDE 3H).
- G. MULTIFOCAL PERINEURAL INVASION IS IDENTIFIED.
- H. NO ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- I. HIGH GRADE PROSTATIC INTRAEPITHELIAL NEOPLASIA IS IDENTIFIED.
- J. PATHOLOGIC TNM STAGE: pT3b N0 MX (See synoptic).
- K. HISTOLOGIC GRADE G3-4.
- L. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY PROSTATE TUMORS

CLINICAL DATA:	PSA value: 26.6
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	3
SECONDARY GLEASON GRADE:	4
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	30%
WEIGHT OF PROSTATE:	57.61gm
TUMOR SIZE:	Maximum dimension: 3.0 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	> 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	Yes - Multifocal
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	Yes
SURGICAL MARGIN INVOLVEMENT:	Widespread tumor involvement at margin
LYMPH NODES EXAMINED:	6
LYMPH NODES POSITIVE:	0
T STAGE, PATHOLOGIC:	pT3b
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file e36d2361-0ef9-4674-acdc-8776129d75db (TCGA-EJ-7788.B66A0868-E91C-4EBF-BE9C-BA55E94552FD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).